TCGA case TCGA-77-A5GA — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Prince Charles Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ce137f49-d12b-4112-825a-e673545f54e5

Demographics
Sex at birth: male; Country of residence at enrollment: Australia; Age at index: 76 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.0 years (27,762 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,280 days (3.5 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Lentigo maligna: ICD-O-3 morphology code: 8742/2; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: Prior primary; Age at diagnosis: 62.2 years (22,708 days); Days to diagnosis: -5,054 days (-13.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Lentigo maligna: ICD-O-3 morphology code: 8742/2; Tissue or organ of origin: Skin of other and unspecified parts of face; Classification of tumor: Prior primary; Age at diagnosis: 62.5 years (22,827 days); Days to diagnosis: -4,935 days (-13.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contacts recording only the day: day 36, day 1,280.

Other clinical attributes
- DLCO (% of predicted): 42; FEV1/FVC before bronchodilator (%): 68; FEV1 before bronchodilator (% of reference): 132.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 99; Tobacco smoking onset year: 1949; Tobacco smoking quit year: 1982.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-77-A5GA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 70 mg.
  Slide TCGA-77-A5GA-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-77-A5GA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-77-A5GA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Forehead; Other malignancy histological type: Hutchinson's Melonotic Freckle.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Face; Other malignancy histological type: Hutchinson's Melonotic Freckle.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: unknown treatment history.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,280 days; disease-specific survival: no event (censored), 1,280 days; disease-free interval: no event (censored), 1,280 days; progression-free interval: no event (censored), 1,280 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-77-A5GA-01): tumor purity 0.26, ploidy 3.47, whole-genome doublings 1 (call status: maf_call).
